Somatic mutation profile of tumor specimen RC-B65F-TBP1-A (aliquot RC-B65F-TBP1-A-1-0-D-A93N-47) from RC case RC-B65F, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatosplenic T-cell lymphoma; Tissue or organ of origin: Liver; Age at diagnosis: 27.3 years (9,988 days).
Specimen RC-B65F-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24f719dd-e551-46d1-9094-2494dba4f6b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B65F-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B65F-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffc10933-bec5-4008-aca4-a5a5ab544441

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- COL5A1 | c.65del p.P22Rfs*22 | Frame Shift Del (DEL) | VAF 2/20 reads (10%) | catalogued as rs1284706958; called by pindel, varscan2
- GIMAP7 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs772280855, COSV57960641; called by muse, mutect2, varscan2
- NOTCH3 | c.4618C>G p.R1540G | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV54644205; called by muse, mutect2, varscan2
- FANCD2 | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NRXN1 | c.1163C>A p.T388K | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- ODF1 | c.447T>G p.C149W | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); called by muse, mutect2
- SEC24D | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); called by muse, mutect2
- PTEN | c.-366_-363del | 5'UTR (DEL) | VAF 6/37 reads (16%) | catalogued as rs1365232630; called by mutect2, pindel
